Somatic mutation profile of tumor specimen TARGET-40-PAMHYN-01A (aliquot TARGET-40-PAMHYN-01A-01D) from TARGET case TARGET-40-PAMHYN, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.6 years (3,499 days).
Specimen TARGET-40-PAMHYN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b6c8dd0-371c-4a66-9e67-14b5512dad0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMHYN-10A (Blood Derived Normal), aliquot TARGET-40-PAMHYN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21a32e7d-e209-42f4-bffc-290b5c95000a

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, RNA 2, Intron 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.3707G>A p.R1236H | Missense Mutation (SNP) | VAF 150/456 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.382); catalogued as rs772473191; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLA2G3 | c.773G>T p.W258L | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV53208648; called by muse, mutect2, varscan2
- PPEF2 | c.517_519del p.E173del | In Frame Del (DEL) | VAF 112/420 reads (27%) | catalogued as rs1376663797; called by pindel, varscan2
- RELN | c.4403C>T p.A1468V | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV58999007; called by muse, mutect2, varscan2
- TMEM167A | c.55T>G p.C19G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV71816091; called by muse, mutect2, varscan2
- UBE3A | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587784517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWA3B | c.2160G>C p.K720N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as rs748853853, COSV68245306; called by muse, varscan2
- WNK4 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53820243; called by muse, mutect2, varscan2
- DDX24 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMC7 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRK1 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- KCNC2 | c.803C>A p.T268K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- KCNC2 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR1Q1 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 160/319 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PIGK | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RESF1 | c.3085A>T p.S1029C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RUVBL2 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKR1D1 | c.120G>A p.S40= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs371285423; called by muse, mutect2, varscan2
- POLE | c.4932G>A p.S1644= | Silent (SNP) | VAF 67/203 reads (33%) | catalogued as rs1057522607, COSV100267735; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNE1 | c.17619T>A p.I5873= (on ENST00000367255 / NM_182961.4; = p.I5802= on NM_033071.3) | Silent (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- ZC3H12A | c.384G>A p.E128= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs149597888; called by muse, mutect2, varscan2
- AL133216.2 | n.6030G>T | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- C8orf44-SGK3 | c.-121-25965G>A | Intron (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- LPAL2 | n.240G>A | RNA (SNP) | VAF 65/106 reads (61%) | catalogued as rs201539316; called by muse, mutect2, varscan2
- PROX2 | c.*749C>T | 3'UTR (SNP) | VAF 41/113 reads (36%) | called by muse, mutect2, varscan2
- TAGLN | c.461+56T>A | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
